MMRF case MMRF_1837 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/31390787-8aaf-4aa2-bbd2-330e0ad4bfba

Demographics
Sex at birth: female; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.6 years (22,119 days); ISS stage: II; Days to last known disease status: 1,092 days (3.0 years); Days to last follow up: 1,092 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 76 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 124 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 125 days; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 216 days; Days to treatment end: 700 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 216 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 693 days (1.9 years); Days to treatment end: 776 days (2.1 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 776 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 3): M Protein 2.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.49 mg/dL; Immunoglobulin G 42 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.82 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.56 ×10⁹/L; Platelets 506 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 31 g/L; Total Protein 9.6 g/dL; Glucose 5.72 mmol/L; C-Reactive Protein 0.69 mg/dL.
- Day 78 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 9.12 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 150 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 1.75 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6.22 mmol/L.
- Day 196: Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 329: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 4.86 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.26 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.92 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 441: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.782 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 4.23 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 3.9 g/dL; Glucose 5.67 mmol/L.
- Day 511 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.78 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 4.57 mmol/L.
- Day 623 (ECOG 1): Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.19 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 700 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.36 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 4.51 mmol/L.
- Day 819 (ECOG 1): Hemoglobin 8.56 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Glucose 5.06 mmol/L.
- Day 882 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.08 µg/mL; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.93 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.7 g/dL; Glucose 4.79 mmol/L.
- Day 973: M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 7.75 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 0.7 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 0.93 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 1,092 (ECOG 1): Hemoglobin 8 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 223 ×10⁹/L.

Other clinical attributes
- Day -14: Weight: 75 kg; Height: 157 cm.

Biospecimens (2 samples)
- Sample MMRF_1837_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1837_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
